Somatic mutation profile of tumor specimen TARGET-15-SJMPAL004013-04A.1 (aliquot TARGET-15-SJMPAL004013-04A.1-01D) from TARGET case TARGET-15-SJMPAL004013, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (645 days).
Specimen TARGET-15-SJMPAL004013-04A.1: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a35d0d54-a720-4d14-870d-3340997d7258.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL004013-15A (Fibroblasts from Bone Marrow Normal), aliquot TARGET-15-SJMPAL004013-15A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb7b1185-ef3f-4f21-b076-41e6b9edc919

The open-access MAF lists 283 somatic variants for this specimen: 200 protein-altering or splice-affecting, 58 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 58, Frame Shift Ins 25, Intron 10, Nonsense Mutation 7, 3'UTR 6, Splice Site 4, RNA 3, 5'UTR 2, 5'Flank 2, 3'Flank 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 89/156 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 121/240 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABLIM2 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs930269484; called by muse, mutect2, varscan2
- ACOX3 | c.1988A>G p.Y663C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1391013318; called by muse, mutect2, varscan2
- ACSL1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs1054480669; called by mutect2, varscan2
- APBA2 | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.529); catalogued as rs1391730292; called by muse, mutect2, varscan2
- ARID1B | c.2941G>C p.A981P | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.69); catalogued as COSV51675149; called by muse, mutect2, varscan2
- ASB9 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs964549174; called by muse, mutect2, varscan2
- BEND2 | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as rs1482831613; called by muse, mutect2, varscan2
- BICC1 | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs200282277; called by muse, mutect2, varscan2
- BICRAL | c.1321C>A p.H441N | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV58403862; called by muse, mutect2
- BOD1L1 | c.6731G>T p.G2244V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV50009037; called by muse, mutect2, varscan2
- CDH10 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.826); catalogued as COSV100052573, COSV52602317; called by muse, mutect2, varscan2
- CFH | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1300493671, COSV62776836; called by muse, mutect2, varscan2
- CLDN8 | c.105C>A p.F35L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54525326; called by muse, mutect2, varscan2
- CLOCK | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1409661658; called by muse, mutect2, varscan2
- CLSTN2 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1216664527, COSV71725778; called by muse, mutect2
- CNTRL | c.6730C>T p.R2244W | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1240275107, COSV104379991; called by muse, mutect2, varscan2
- COX7B2 | c.147C>G p.F49L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57224153; called by muse, mutect2, varscan2
- CYP1B1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99572722; called by muse, mutect2, varscan2
- ERLIN2 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1331977591, COSV99379409; called by muse, mutect2
- FLNC | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs747837803, COSV57966273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FREM3 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61679074; called by muse, mutect2
- FUT10 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 32/182 reads (18%) | catalogued as rs1009239899; called by muse, mutect2, varscan2
- GALNT9 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as rs1237415738; called by muse, mutect2, varscan2
- HECTD3 | c.2071G>A p.V691M | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs551597519, COSV100938208; called by muse, mutect2, varscan2
- HMGB4 | c.365A>T p.Q122L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs777407060; called by muse, mutect2, varscan2
- HSDL1 | c.924G>A p.W308* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as rs1283448775; called by muse, mutect2, varscan2
- IL12RB1 | c.419A>C p.E140A | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1228769335; called by muse, mutect2, varscan2
- IMMT | c.1740G>T p.M580I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.046); catalogued as COSV54479849; called by mutect2, varscan2
- IP6K1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); catalogued as rs757004314, COSV58662971; called by muse, mutect2, varscan2
- ITPR3 | c.7465C>A p.L2489I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100951965; called by muse, varscan2
- JARID2 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs768784464; called by mutect2, varscan2
- KRT8 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as rs147715492, COSV53177970, COSV99509910; called by muse, mutect2, varscan2
- LONRF1 | c.1901A>G p.D634G | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772493012; called by muse, mutect2, varscan2
- LRP1 | c.10765G>A p.A3589T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs776806646; called by muse, varscan2
- MOCS3 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99724132; called by muse, mutect2, varscan2
- MOV10L1 | c.3209G>A p.R1070Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as rs201034284; called by muse, mutect2, varscan2
- MYO3A | c.3526A>G p.T1176A | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs773127499; called by muse, mutect2, varscan2
- N4BP2 | c.3527T>C p.V1176A | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1390737362; called by muse, mutect2, varscan2
- NDST1 | c.1492T>C p.Y498H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99938677; called by muse, mutect2, varscan2
- PAN2 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs140591449; called by mutect2, varscan2
- PBX4 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99232478; called by muse, mutect2, varscan2
- PCDHB16 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV99502928; called by muse, mutect2
- PIEZO2 | c.3062A>G p.Q1021R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57438596; called by muse, mutect2
- PIP4K2B | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs779324819; called by muse, mutect2, varscan2
- PIP5K1A | c.316C>T p.R106C (on ENST00000368888 / NM_001135638.2; = p.R93C on NM_003557.3) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs763482724, COSV62960664; called by muse, mutect2, varscan2
- PMS2 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs63751284, COSV56220302, COSV99764591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPIL4 | c.1349A>G p.D450G | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs762755126; called by muse, mutect2, varscan2
- PSMB8 | c.686G>T p.R229L (on ENST00000374882 / NM_148919.4; = p.R225L on NM_004159.5) | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV62755537; called by muse, mutect2
- PTCH1 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.29); catalogued as rs762040036, COSV100108122; ClinVar: uncertain significance; called by muse, varscan2
- PYGO1 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57346392; called by muse, mutect2, varscan2
- RAB3B | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs201157918; called by muse, mutect2, varscan2
- RACGAP1 | c.1097T>C p.V366A | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs767233141; called by muse, mutect2, varscan2
- SBNO1 | c.2372dup p.K792Efs*24 (on ENST00000420886; = p.K791Efs*24 on NM_018183.5) | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs1253266356; called by mutect2, varscan2
- SCNN1A | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.098); catalogued as COSV57435059, COSV99964801; called by muse, mutect2
- SLC25A31 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs368916292; called by muse, mutect2, varscan2
- SLC38A8 | c.388+1G>A p.X130_splice | Splice Site (SNP) | VAF 29/44 reads (66%) | catalogued as rs149436446; called by muse, varscan2
- SLCO2A1 | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs754606083; called by muse, mutect2, varscan2
- SPDYE3 | c.1007dup p.R337Afs*2 | Frame Shift Ins (INS) | VAF 25/102 reads (25%) | catalogued as rs755535684; called by mutect2, pindel, varscan2
- SV2B | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs149291154; called by mutect2, varscan2
- SYDE2 | c.1862T>C p.L621P | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52314968; called by muse, varscan2
- SYNE1 | c.8780G>A p.R2927H (on ENST00000367255 / NM_182961.4; = p.R2934H on NM_033071.3) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as rs148998248, COSV54997608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TACC2 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1026573145; called by muse, mutect2
- TCOF1 | c.2032T>C p.S678P (on ENST00000377797 / NM_001135243.1; = p.S601P on NM_000356.4) | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as rs1287599838; called by muse, mutect2, varscan2
- TLCD3A | c.719T>C p.L240P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770077057; called by mutect2, varscan2
- TNRC18 | c.8738A>G p.D2913G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51873945; called by muse, mutect2, varscan2
- TRIM60 | c.1323C>A p.N441K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.239); catalogued as COSV61971749; called by mutect2, varscan2
- UGT1A6 | c.1438C>T p.L480F | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433976375; called by muse, mutect2, varscan2
- VSTM2A | c.94T>A p.F32I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV56496298; called by muse, mutect2
- WDR64 | c.1758C>G p.I586M | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV100844046, COSV63796327, COSV63800267; called by muse, mutect2, varscan2
- ZNF232 | c.543G>C p.E181D | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.905); catalogued as COSV100005515; called by muse, mutect2
- ZNF274 | c.1801C>T p.R601C (on ENST00000610905; = p.R496C on NM_016324.3) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs749258654, COSV58766980, COSV58767578; called by muse, mutect2, varscan2
- ABCB10 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2
- ACAA1 | c.626+1G>T p.X209_splice | Splice Site (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- ACTC1 | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRF4 | c.629C>A p.A210D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2
- ADGRV1 | c.12454G>T p.G4152W | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- ADGRV1 | c.14261T>C p.V4754A | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AGRN | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- AHNAK2 | c.14830G>T p.A4944S | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2
- ARHGAP23 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- BAHCC1 | c.6228dup p.K2077Qfs*18 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- BBX | c.1807dup p.I603Nfs*19 | Frame Shift Ins (INS) | VAF 17/101 reads (17%) | called by mutect2, pindel, varscan2
- BCL2L2 | c.319T>C p.C107R | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- BOD1L1 | c.5368G>A p.A1790T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- C14orf119 | c.136T>C p.F46L | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- C2CD3 | c.3450A>G p.I1150M | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAPN14 | c.1570A>G p.T524A | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CCDC92 | c.469T>A p.Y157N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CDR2 | c.40dup p.E14Gfs*20 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- CEP85 | c.995G>T p.S332I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.19); called by muse, varscan2
- CEP89 | c.1973dup p.K659Efs*59 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, pindel
- CHRD | c.706_707insT p.G236Vfs*15 | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- CNOT1 | c.5792dup p.C1932Vfs*30 | Frame Shift Ins (INS) | VAF 14/117 reads (12%) | called by mutect2, pindel, varscan2
- CNTN2 | c.792dup p.G265Wfs*24 | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- CNTROB | c.1835T>C p.V612A | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- COL4A3 | c.1315+2T>A p.X439_splice | Splice Site (SNP) | VAF 21/114 reads (18%) | called by muse, mutect2, varscan2
- COL6A6 | c.4533+2T>A p.X1511_splice | Splice Site (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- CP | c.316T>C p.Y106H | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2
- CRAMP1 | c.3221C>T p.A1074V | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- CREBBP | c.2113+8T>C | Splice Region (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- CRPPA | c.904C>G p.L302V (on ENST00000407010 / NM_001368197.1; = p.L252V on NM_001101417.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CSF1R | c.1904A>G p.K635R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTRC | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- CYP4F11 | c.1047dup p.Y350Ifs*17 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- DCAKD | c.566T>C p.V189A | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DDX17 | c.439T>C p.Y147H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFHD1 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2
- EFHD2 | c.650A>G p.E217G | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- FAM189A1 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- FAM91A1 | c.1133T>C p.I378T | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FANCM | c.3680T>C p.L1227S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FAT1 | c.7801T>C p.Y2601H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FBXO47 | c.983T>C p.L328P | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FUT6 | c.883T>C p.F295L | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GALK1 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.409); called by muse, varscan2
- GALNT13 | c.198T>G p.I66M | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- GFAP | c.578T>G p.L193R | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPSM1 | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- HERC5 | c.2408T>A p.L803* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- HLX | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- HS3ST1 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- HSCB | c.170dup p.C58Lfs*11 | Frame Shift Ins (INS) | VAF 9/71 reads (13%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.1843A>C p.K615Q | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL2RG | c.232T>C p.S78P | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ITIH3 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- JAK3 | c.2099A>G p.Q700R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, varscan2
- KATNIP | c.1693dup p.D565Gfs*16 | Frame Shift Ins (INS) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- KCNJ4 | c.1255T>C p.F419L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNMB2 | c.170G>C p.C57S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KDM3B | c.4682dup p.L1561Ffs*5 | Frame Shift Ins (INS) | VAF 10/90 reads (11%) | called by mutect2, pindel, varscan2
- KIAA1671 | c.4474T>C p.S1492P | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- KIF2C | c.1523A>T p.Q508L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2
- KLHL18 | c.293dup p.N98Kfs*7 | Frame Shift Ins (INS) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- KLKB1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- KRT31 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- LCT | c.4063T>C p.Y1355H | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LIMD2 | c.218dup p.L74Afs*24 | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- MAP4K2 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- MICAL2 | c.4721T>C p.F1574S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MMP16 | c.1322C>A p.S441* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- MROH6 | c.1684dup p.C562Lfs*15 | Frame Shift Ins (INS) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- MS4A15 | c.15dup p.A6Rfs*38 | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- MUC16 | c.30052dup p.T10018Nfs*2 | Frame Shift Ins (INS) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- NAALADL2 | c.1792del p.T598Hfs*2 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- NISCH | c.2114T>G p.I705S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NR2F2 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OCRL | c.2572A>G p.N858D | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ODF2 | c.247dup p.E83Gfs*25 (on ENST00000434106 / NM_153433.2; = p.E127Gfs*25 on NM_153432.1 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- OR1J4 | c.888C>A p.D296E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.242); called by muse, varscan2
- OTOF | c.4982A>G p.E1661G (on ENST00000272371 / NM_194248.3; = p.E894G on NM_004802.4) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PAPLN | c.3782dup p.C1262Lfs*30 (on ENST00000554301; = p.C1235Lfs*30 on NM_173462.4) | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | called by mutect2, pindel
- PBX3 | c.657_658dup p.S220Kfs*8 | Frame Shift Ins (INS) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- PCF11 | c.148_149delinsGATCTCC p.F50Dfs*34 | Frame Shift Ins (INS) | VAF 27/62 reads (44%) | called by pindel, varscan2*
- PEX13 | c.443A>T p.D148V | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PHACTR4 | c.1534A>G p.K512E (on ENST00000373839 / NM_001350159.2; = p.K522E on NM_023923.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.031); called by mutect2, varscan2
- PHB | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLIN4 | c.3596A>G p.H1199R (on ENST00000301286; = p.H1214R on NM_001367868.2) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- POLR3B | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PTCH1 | c.4135G>A p.V1379I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- PTCH1 | c.4009G>A p.A1337T | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTCH1 | c.3691G>T p.V1231L | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, varscan2
- R3HCC1 | c.1364G>C p.R455P (on ENST00000411463; = p.R415P on NM_001136108.3) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RASGRF2 | c.3466A>G p.M1156V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.499); called by muse, mutect2
- RASGRP4 | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMBP3 | c.4133T>C p.V1378A | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.068); called by muse, mutect2
- RSRC1 | c.176C>A p.S59* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- RTN3 | c.1333G>A p.D445N (on ENST00000377819 / NM_001265589.2; = p.D426N on NM_201428.3) | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SAMHD1 | c.979A>G p.N327D | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SEC23IP | c.2531T>C p.V844A | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SEMA3A | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- SETD1B | c.5513A>G p.D1838G | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SGPL1 | c.792G>C p.M264I | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC19A2 | c.1469C>G p.S490* | Nonsense Mutation (SNP) | VAF 9/194 reads (5%) | called by muse, mutect2
- SLC25A10 | c.692dup p.E233Gfs*203 | Frame Shift Ins (INS) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- SLC45A4 | c.2095G>A p.A699T (on ENST00000517878 / NM_001286646.2; = p.A648T on NM_001080431.2) | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC9A7 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SMC1B | c.1321T>C p.Y441H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SNCA | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX13 | c.1808G>A p.S603N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- STXBP4 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- TENM1 | c.3607G>C p.G1203R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- THEMIS2 | c.1345T>C p.F449L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.022); called by muse, mutect2
- TKT | c.1667T>C p.I556T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMEM9B | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TNRC18 | c.8512A>G p.I2838V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TOP2B | c.1919_1920insGCCCCAGCTAG p.S640Rfs*51 (on ENST00000264331 / NM_001330700.2; = p.S635Rfs*51 on NM_001068.3) | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- TRAF3 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TST | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.841); called by muse, mutect2
- WDR1 | c.1520G>T p.C507F (on ENST00000382452; = p.C367F on NM_005112.5) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, varscan2
- YOD1 | c.484T>G p.F162V | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBTB3 | c.504dup p.G169Rfs*18 | Frame Shift Ins (INS) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- ZBTB6 | c.1183T>C p.S395P | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZFP37 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); called by mutect2, varscan2
- ZNF142 | c.5177A>G p.H1726R (on ENST00000411696 / NM_001379660.1; = p.H1526R on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF148 | c.1693A>G p.T565A | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF227 | c.567G>C p.Q189H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF234 | c.1922A>T p.Y641F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ZNF367 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- APBA2 | c.696G>A p.E232= | Silent (SNP) | VAF 48/224 reads (21%) | called by muse, mutect2, varscan2
- ARGLU1 | c.312G>A p.E104= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs756574859; called by muse, mutect2, varscan2
- ASIC5 | c.993G>A p.V331= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- BBX | c.2412A>G p.P804= (on ENST00000325805 / NM_001142568.3; = p.P774= on NM_020235.7) | Silent (SNP) | VAF 23/198 reads (12%) | called by muse, mutect2, varscan2
- BCAS4 | c.261T>C p.S87= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- C1orf115 | c.207G>A p.V69= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- CAMK2D | c.1149A>G p.E383= | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- CCDC91 | c.342A>T p.A114= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- CELSR2 | c.3789C>T p.F1263= | Silent (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- CLCN3 | c.2385A>T p.I795= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- CLCNKB | c.1851T>C p.C617= | Silent (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- CXADR | c.357G>A p.Q119= | Silent (SNP) | VAF 49/97 reads (51%) | catalogued as rs770870922; called by muse, mutect2, varscan2
- DDX60L | c.3396G>A p.K1132= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs1326318161; called by muse, mutect2, varscan2
- DOLPP1 | c.144G>A p.V48= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as COSV59910120; called by muse, mutect2
- ESYT3 | c.870G>A p.V290= | Silent (SNP) | VAF 17/131 reads (13%) | called by muse, mutect2, varscan2
- FBN3 | c.1827C>T p.R609= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs779380293, COSV54479001; called by mutect2, varscan2
- FBXO11 | c.1539A>G p.G513= (on ENST00000403359 / NM_001190274.2; = p.G429= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs920415828; called by muse, mutect2, varscan2
- GNE | c.159T>C p.Y53= (on ENST00000396594 / NM_001128227.3; = p.Y22= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/225 reads (12%) | catalogued as COSV100929933; called by muse, mutect2, varscan2
- HGS | c.141T>C p.N47= | Silent (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- ITGAL | c.1734T>C p.I578= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- KIF14 | c.1914T>A p.S638= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, varscan2
- KLHL36 | c.837C>T p.A279= | Silent (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- KRT81 | c.943C>T p.L315= | Silent (SNP) | VAF 16/277 reads (6%) | called by muse, mutect2
- KRT83 | c.60C>A p.V20= | Silent (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- LRRIQ1 | c.204A>G p.E68= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- MED1 | c.3678T>C p.S1226= | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- MTARC2 | c.684G>A p.E228= | Silent (SNP) | VAF 9/83 reads (11%) | called by muse, varscan2
- MTARC2 | c.747G>A p.E249= | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, varscan2
- MUC4 | c.6279C>T p.H2093= | Silent (SNP) | VAF 53/457 reads (12%) | catalogued as rs763105506, COSV62159341; called by muse, varscan2
- MYO18B | c.7113C>A p.P2371= | Silent (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- NDUFV1 | c.234C>T p.G78= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as rs749383100, COSV59595988; called by muse, mutect2, varscan2
- NSD2 | c.3063A>G p.T1021= | Silent (SNP) | VAF 12/76 reads (16%) | called by muse, varscan2
- NUP210L | c.4248C>T p.I1416= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs765180961, COSV55159955; called by muse, mutect2, varscan2
- OR2L2 | c.861C>A p.I287= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV63558327; called by muse, mutect2, varscan2
- PITX2 | c.820A>C p.R274= (on ENST00000354925 / NM_001204397.1; = p.R281= on NM_000325.6) | Silent (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- PLXNB3 | c.3339A>G p.V1113= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- PTPRD | c.1383A>G p.Q461= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs756864799; called by muse, mutect2, varscan2
- RASGRP4 | c.888C>A p.G296= | Silent (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- RIPK3 | c.564A>T p.P188= | Silent (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- SCRT1 | c.774G>A p.S258= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1554849861; called by muse, mutect2, varscan2
- SESN3 | c.69G>A p.V23= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- SHH | c.843C>T p.A281= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1473683107; called by muse, mutect2, varscan2
- SHROOM3 | c.4146C>T p.T1382= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs199958812; called by muse, mutect2, varscan2
- SLC2A13 | c.124C>T p.L42= | Silent (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- SNRNP200 | c.5919T>C p.R1973= | Silent (SNP) | VAF 23/190 reads (12%) | catalogued as rs751752388, COSV55531045; called by muse, mutect2, varscan2
- SPEG | c.8187C>T p.P2729= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs533153023, COSV56670302; called by muse, mutect2, varscan2
- SUFU | c.63T>C p.T21= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV64015759; called by muse, mutect2, varscan2
- TBC1D24 | c.735G>A p.L245= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as rs987950301; called by muse, mutect2
- TMEM63B | c.2139A>G p.T713= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs987805180, COSV52478595; called by muse, mutect2, varscan2
- TRGV4 | c.15A>G p.L5= | Silent (SNP) | VAF 42/46 reads (91%) | catalogued as rs1480154225; called by muse, mutect2, varscan2
- UBE4A | c.1923C>T p.R641= (on ENST00000252108 / NM_001204077.2; = p.R648= on NM_004788.4) | Silent (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- UTP20 | c.7494G>A p.E2498= | Silent (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- UTP4 | c.1584A>G p.P528= | Silent (SNP) | VAF 23/256 reads (9%) | catalogued as rs538492909; called by muse, mutect2
- VPS54 | c.2763T>C p.Y921= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as rs760397437; called by mutect2, varscan2
- YJU2 | c.36G>A p.P12= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs368087162, COSV53607462; called by muse, mutect2, varscan2
- ZDHHC23 | c.532T>C p.L178= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs930096656; called by muse, mutect2, varscan2
- ZNF221 | c.213T>C p.N71= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- ZNF644 | c.360T>C p.V120= | Silent (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- ACTN4 | c.*164_*165dup | 3'UTR (INS) | VAF 6/42 reads (14%) | catalogued as rs974574445; called by mutect2, varscan2
- CCDC28B | c.548+160A>G | Intron (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- CCDC74B | c.295+443G>A | Intron (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93735152 G>A | 3'Flank (SNP) | VAF 40/66 reads (61%) | catalogued as rs757591995; called by muse, mutect2, varscan2
- CFL2 | c.*1796T>C | 3'UTR (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- COLQ | c.-17G>A | 5'UTR (SNP) | VAF 16/104 reads (15%) | catalogued as rs568283420; called by muse, mutect2, varscan2
- CTSW | c.1021-25G>A | Intron (SNP) | VAF 8/29 reads (28%) | catalogued as rs376282606; called by muse, mutect2, varscan2
- DPAGT1 | c.282+45A>G | Intron (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- EMSY | c.1363+25A>G | Intron (SNP) | VAF 10/81 reads (12%) | catalogued as rs1051112162; called by muse, mutect2, varscan2
- GVINP1 | n.4068A>T | RNA (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- HMGN2P46 | n.954C>T | RNA (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- INS | c.*21C>A | 3'UTR (SNP) | VAF 36/139 reads (26%) | called by muse, mutect2, varscan2
- ITGA6 | c.2796+21A>G | Intron (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- KCNA2 | c.*1203G>A | 3'UTR (SNP) | VAF 12/112 reads (11%) | catalogued as rs958979840, COSV100315920; called by muse, mutect2, varscan2
- LILRB5 | c.1630-77G>C | Intron (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- LIMS1 | c.-5+18811G>A | Intron (SNP) | VAF 10/98 reads (10%) | catalogued as rs1242660614; called by muse, mutect2
- LIPT2 | chr11:74498012 T>C | 5'Flank (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- NELL2 | chr12:44876717 G>A | 5'Flank (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- NOD2 | c.73+60C>T | Intron (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- PDE4DIP | c.637-7316A>G | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as rs782634270; called by muse, mutect2, varscan2
- PSMG3-AS1 | n.3661T>C | RNA (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- RN7SL759P | chr15:20572683 G>C | 3'Flank (SNP) | VAF 27/283 reads (10%) | called by muse, mutect2
- SULF1 | c.*461A>G | 3'UTR (SNP) | VAF 42/76 reads (55%) | called by muse, mutect2, varscan2
- USP15 | c.-10G>C | 5'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- XPA | c.*312A>C | 3'UTR (SNP) | VAF 46/46 reads (100%) | called by muse, mutect2, varscan2
